Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6164, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6164-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

SURGICAL PATHOLOGY REPORT

* Addendum *

[REDACTED]

....

Clinical Diagnosis & History:
Sigmoid colon cancer.

Specimens Submitted:

- 1: SP: Sigmoid colon [REDACTED]
- 2: SP: Distal margin [REDACTED]
- 3: SP: Proximal margin [REDACTED]

DIAGNOSIS:

1. LARGE BOWEL, SIGMOID; RESECTION:
- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: SIGMOID.
- TUMOR SIZE: LENGTH IS 5.3 CM, WIDTH IS 5.5 CM AND MAXIMAL THICKNESS IS 1.1 CM.
- GROSS CONFIGURATION: ULCERATING INFILTRATIVE.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): NOT IDENTIFIED.
- TUMOR INVASION: INVASION INTO SUBSEROZA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- EXTRAMURAL VENOUS INVASION IS IDENTIFIED.
- PERINEURAL INVASION IS IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: MELANOSIS COLI.
- THE PATHOLOGIC STAGE IS (AJCC 2002): pT3
- LYMPH NODES: THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED: 0/14 (PEDICLE 1: 0/12, PEDICLE 2: 0/2)).
- THE PATHOLOGIC STAGE IS (AJCC 2002): pN0
- THE RESULTS OF IMMUNOHISTOCHEMICAL STAINS FOR MISMATCH REPAIR PROTEINS WILL BE REPORTED IN AN ADDENDUM.
2. COLON, DISTAL MARGIN; EXCISION:
- BENIGN SEGMENT OF COLON WITH MELANOSIS COLI.
3. COLON, PROXIMAL MARGIN; EXCISION:
- BENIGN SEGMENT OF COLON WITH MELANOSIS COLI.

** Continued on next page **

[page 2 of 4]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1.) The specimen is received fresh and is labeled "Sigmoid colon". It consists of a 18.2 cm in length and a 5.5 cm in circumference of rectosigmoid colon. The serosa is glistening, smooth, tan-pink. The serosal surface is inked black and the specimen is opened to reveal a 5.3 (l) x 5.5 (w) cm, well-circumscribed, centrally cavitated and necrotic, serpiginous bordered, sessile mass, located 9.5 cm from the (probable) distal margin, occupying the full circumference of the lumen (designated Mass #1). Serial sectioning reveals Mass #1 to invade through the muscularis into the pericolic fat, to a depth of 1.1 cm, which is 2.8 cm from the closest radial margin. In addition, 1.1 cm distal to Mass #1, is a 0.4 (l) x 0.4 (w), well-circumscribed, smooth, homogenous tan nodule, located 3.9 cm away from the distal margin (designated Nodule #1). Sectioning reveals Nodule #1 to remain confined to the mucosa. The remaining mucosa is unremarkable. The specimen is submitted for lymph node dissection. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted for Mass #1.

Summary of sections:

PM (probable) proximal margin
DM (probable) distal margin
RM -- radial margin
M1 Mass #1
N1 -- Nodule #1
M1N1 Mass #1 and Nodule #1
U -- uninvolved mucosa
P1 pedicle one lymph nodes
BP1 bisected pedicle one lymph nodes
P2pedicle two lymph nodes
BP2bisected pedicle two lymph nodes

2). The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 2 x 1.8 x 1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

Undesignated

** Continued on next page **

[page 3 of 4]
3). The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a white plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.5 x 1 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

Summary of Sections:
Part 1: SP: Sigmoid colon (nyt)

Block	Sect.	Site	PCs
2		bpl	4
1		DM	3
5		M1	5
1		M1N1	1
1		N1	1
4		p1	12
3		p2	3
1		PM	4
1		RM	1
1		U	2

Part 2: SP: Distal margin (nyt)

Block	Sect.	Site	PCs
1		U	1

Part 3: SP: Proximal margin (nyt)

Block	Sect.	Site	PCs
1		U	1

Addendum Diagnosis
Part 1. Results of immunohistochemical staining for DNA mismatch repair proteins are as follows:
MLH1: Staining present in tumor

** Continued on next page **

[page 4 of 4]
MSH2: Staining present in tumor
MSH6: Staining present in tumor
PMS2: Staining present in tumor

Conclusion: Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** End of Report **

Source: NCI Genomic Data Commons file 299a1ff8-3075-4d73-a406-3d9ff97c1821 (TCGA-CM-6164.7A64EA09-BB1A-4665-8EF4-E6F689731373.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).